Somatic mutation profile of tumor specimen TCGA-23-1110-01A (aliquot TCGA-23-1110-01A-01D-0428-01) from TCGA case TCGA-23-1110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.1 years (15,383 days).
Specimen TCGA-23-1110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a790847-c604-4f46-84be-c814ecedb594.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1110-10A (Blood Derived Normal), aliquot TCGA-23-1110-10A-01D-0428-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7444fc72-6170-47bb-9459-6fdee5c29c9f

The open-access MAF lists 142 somatic variants for this specimen: 108 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 30, Frame Shift Del 9, Splice Site 6, Nonsense Mutation 5, Nonstop Mutation 2, 5'Flank 1, RNA 1, Intron 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 106/114 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV62323671, COSV62324776; called by muse, mutect2, varscan2
- ADGRB3 | c.4072C>A p.Q1358K | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV53253821; called by muse, mutect2, varscan2
- AGBL1 | c.2169G>C p.E723D | Missense Mutation (SNP) | VAF 332/739 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV101224349; called by muse, mutect2, varscan2
- AHNAK | c.15374C>G p.S5125C | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57222869; called by muse, mutect2, varscan2
- ANKS6 | c.2078C>G p.A693G | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs756412369, COSV62051295; called by muse, mutect2, varscan2
- ARAP2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 248/561 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100395317; called by muse, mutect2, varscan2
- ARAP2 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 251/565 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100395318; called by muse, mutect2, varscan2
- ARHGAP15 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV54510235; called by muse, mutect2
- ATP7B | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 68/71 reads (96%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs559705781, COSV54441307; called by muse, mutect2, varscan2
- BIRC3 | c.1607C>G p.T536R | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV54818673; called by muse, mutect2, varscan2
- BOD1L1 | c.4831A>G p.K1611E | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV50031763; called by muse, mutect2, varscan2
- BRD8 | c.1014C>A p.N338K (on ENST00000254900 / NM_139199.2; = p.N411K on NM_006696.4) | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99137744; called by muse, mutect2
- C1orf158 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 96/504 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV55346313, COSV55347418; called by muse, mutect2, varscan2
- C7 | c.1754A>C p.E585A | Missense Mutation (SNP) | VAF 115/228 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV57477613; called by muse, mutect2, varscan2
- CACNA1S | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62941938; called by muse, mutect2, varscan2
- CD8A | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs755895247, COSV52156850, COSV52158608; called by muse, mutect2, varscan2
- CDH16 | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55338381; called by muse, mutect2, varscan2
- CDK13 | c.3148G>T p.G1050C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51703585; called by muse, mutect2, varscan2
- CHM | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV62565701; called by muse, mutect2, varscan2
- CX3CR1 | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100843299; called by muse, mutect2
- DDX58 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65884082; called by muse, mutect2, varscan2
- DKK2 | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528677483, COSV53396515, COSV53396966, COSV53400713; called by muse, mutect2, varscan2
- DNASE2B | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV65743647; called by muse, mutect2, varscan2
- DUOX1 | c.2886C>T p.I962= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as COSV58483505, COSV58484331; called by muse, mutect2, varscan2
- EPB42 | c.1001T>A p.M334K (on ENST00000441366 / NM_001114134.2; = p.M364K on NM_000119.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55750792; called by muse, mutect2, varscan2
- EPHX1 | c.184-2A>T p.X62_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | catalogued as COSV55302597; called by muse, mutect2, varscan2
- EZHIP | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV57956975; called by muse, mutect2, varscan2
- FARP1 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV60343030; called by muse, mutect2, varscan2
- FGA | c.2096T>A p.L699Q | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV57398673; called by muse, mutect2, varscan2
- FOXA2 | c.112A>C p.N38H (on ENST00000377115 / NM_153675.3; = p.N44H on NM_021784.5) | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1247284954, COSV65796704, COSV65796725; called by muse, mutect2, varscan2
- FRMPD4 | c.2894C>A p.P965Q | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.095); catalogued as COSV66219716; called by muse, mutect2, varscan2
- FSTL5 | c.1599A>T p.K533N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60213555; called by muse, mutect2, varscan2
- GMPR2 | c.883G>C p.V295L (on ENST00000355299 / NM_001351022.2; = p.V313L on NM_016576.5) | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV57469689; called by muse, mutect2, varscan2
- GON4L | c.907C>G p.H303D | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55198805; called by muse, mutect2, varscan2
- GPER1 | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52469946; called by muse, mutect2, varscan2
- HRC | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1387230635, COSV53257715; called by muse, mutect2, varscan2
- IGSF22 | c.811-1G>C p.X271_splice | Splice Site (SNP) | VAF 32/69 reads (46%) | catalogued as COSV60036756; called by muse, mutect2, varscan2
- JMJD1C | c.6923T>A p.V2308E | Missense Mutation (SNP) | VAF 92/460 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59513569, COSV59516897; called by muse, mutect2, varscan2
- KCNA5 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52907594; called by muse, mutect2, varscan2
- KCNU1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV67758268; called by muse, mutect2, varscan2
- KMT2C | c.6301C>G p.P2101A | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV51472911; called by muse, mutect2, varscan2
- KRT35 | c.1319A>C p.N440T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV55843936; called by muse, mutect2, varscan2
- LCE5A | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as rs761623532, COSV57501139; called by muse, mutect2, varscan2
- LPIN1 | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 181/270 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV56768195; called by muse, mutect2, varscan2
- LRRC6 | c.723C>A p.D241E | Missense Mutation (SNP) | VAF 90/481 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs776328128, COSV51545002; called by muse, mutect2, varscan2
- LTF | c.1357G>C p.G453R | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99212197; called by muse, mutect2, varscan2
- MAPKAP1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV56371797; called by muse, mutect2, varscan2
- MBTD1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64503957; called by muse, mutect2, varscan2
- MFN1 | c.104T>A p.F35Y | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV54941273, COSV99764248; called by muse, mutect2, varscan2
- MORC1 | c.223+1G>T p.X75_splice | Splice Site (SNP) | VAF 193/740 reads (26%) | catalogued as COSV51725916; called by muse, mutect2, varscan2
- MOS | c.1041A>T p.*347Cext*? | Nonstop Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV61336726; called by muse, mutect2, varscan2
- MOSPD2 | c.1388C>A p.S463* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV100996958; called by muse, mutect2
- MUC17 | c.11951C>A p.S3984Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV60296749; called by muse, mutect2, varscan2
- MXRA5 | c.2629C>G p.P877A | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54243266; called by muse, mutect2
- MYO15A | c.7705T>A p.F2569I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV52761422, COSV99232000; called by muse, mutect2, varscan2
- MYOM2 | c.3951C>A p.D1317E | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs568923144, COSV50741608; called by muse, mutect2, varscan2
- NDUFV3 | c.325T>G p.*109Gext*5 (on ENST00000340344 / NM_001001503.2; = p.*474Gext*5 on NM_021075.4) | Nonstop Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as COSV61088167; called by muse, mutect2, varscan2
- NR6A1 | c.184A>T p.I62F (on ENST00000487099 / NM_033334.4; = p.I58F on NM_001489.5) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60635659; called by muse, mutect2, varscan2
- NSG2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 86/90 reads (96%) | SIFT tolerated (0.4); PolyPhen benign (0.175); catalogued as COSV100292956; called by muse, mutect2, varscan2
- NTNG1 | c.1286A>C p.H429P | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV64276101; called by muse, mutect2, varscan2
- OR10J1 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV71129247; called by muse, mutect2, varscan2
- OR5AN1 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 144/593 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.319); catalogued as COSV58322499; called by muse, mutect2, varscan2
- OR5H2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 81/580 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769324469, COSV100788878, COSV62351407; called by muse, mutect2, varscan2
- PRDM7 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57987427; called by muse, mutect2, varscan2
- PTPRK | c.3740C>A p.T1247K (on ENST00000368215 / NM_001291984.2; = p.T1248K on NM_002844.4) | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63903188; called by muse, mutect2, varscan2
- PWWP3A | c.379C>T p.H127Y (on ENST00000627377; = p.H126Y on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV60905417; called by muse, mutect2
- RABEP2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753049047, COSV62868850; called by muse, mutect2
- RDH13 | c.861C>G p.Y287* (on ENST00000415061 / NM_001145971.2; = p.Y216* on NM_138412.4) | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs757565961, COSV52561953; called by muse, mutect2, varscan2
- RFTN1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 63/69 reads (91%) | catalogued as rs754652628, COSV61918069; called by muse, mutect2, varscan2
- RFX3 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 90/718 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs370801268; called by muse, mutect2, varscan2
- RIN2 | c.175G>T p.G59C (on ENST00000255006 / NM_001242581.1; = p.G10C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV54791387; called by muse, mutect2
- SCN11A | c.2000C>A p.P667Q | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100182711; called by muse, mutect2, varscan2
- SGO2 | c.3318G>T p.K1106N | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.211); catalogued as COSV63416516; called by muse, mutect2, varscan2
- SLC22A10 | c.241T>A p.S81T | Missense Mutation (SNP) | VAF 384/537 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV60422722; called by muse, mutect2, varscan2
- SLC25A48 | c.152G>T p.R51M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99192249; called by muse, mutect2, varscan2
- SMU1 | c.26+1G>A p.X9_splice | Splice Site (SNP) | VAF 52/179 reads (29%) | catalogued as COSV68140154; called by muse, mutect2, varscan2
- SULF2 | c.2068C>A p.Q690K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100737486; called by muse, mutect2
- SUSD6 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61366094; called by muse, mutect2, varscan2
- SYNE2 | c.7808T>C p.L2603P | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV59960460; called by muse, mutect2, varscan2
- TARS1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV54310994; called by muse, mutect2, varscan2
- TGS1 | c.2177C>G p.A726G | Missense Mutation (SNP) | VAF 78/534 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV52701934; called by muse, mutect2, varscan2
- TMC7 | c.1459T>A p.W487R | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58585729; called by muse, mutect2, varscan2
- TMEM53 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62408153; called by muse, mutect2, varscan2
- TNS1 | c.4538A>G p.Q1513R | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1380677122, COSV50733191; called by muse, mutect2, varscan2
- TRIM10 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 97/641 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.827); catalogued as COSV64998927; called by muse, mutect2, varscan2
- TTN | c.78001T>C p.Y26001H (on ENST00000591111; = p.Y18577H on NM_003319.4) | Missense Mutation (SNP) | VAF 84/314 reads (27%) | PolyPhen probably damaging (0.998); catalogued as COSV59981717, COSV60212781; called by muse, mutect2, varscan2
- UGT1A8 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 128/522 reads (25%) | catalogued as rs200115254, COSV65082712; called by muse, mutect2, varscan2
- UTRN | c.2161A>G p.M721V | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV62342048; called by muse, mutect2, varscan2
- VARS2 | c.2261G>T p.R754L | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV58913691, COSV58914684; called by muse, mutect2, varscan2
- ZBED1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs771759980, COSV100586124; called by muse, mutect2, varscan2
- ZCCHC4 | c.499A>C p.K167Q | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV57182461; called by muse, mutect2, varscan2
- ZNF135 | c.883G>A p.E295K (on ENST00000313434 / NM_001289401.2; = p.E307K on NM_003436.4) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1212991134, COSV100536368, COSV100536935; called by muse, mutect2, varscan2
- ZNF235 | c.1673T>A p.L558H | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52157605; called by muse, mutect2, varscan2
- ZNF365 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV67925959; called by muse, mutect2, varscan2
- ZNF777 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV56099145; called by muse, mutect2, varscan2
- BVES | c.465_479delinsT p.L155Ffs*7 | Frame Shift Del (DEL) | VAF 89/643 reads (14%) | called by pindel, varscan2*
- CA1 | c.357del p.H120Tfs*2 | Frame Shift Del (DEL) | VAF 65/169 reads (38%) | called by mutect2, pindel, varscan2
- CACNA1A | c.654_672del p.I219Lfs*19 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- CCDC158 | c.2280_2286+9del p.X760_splice | Splice Site (DEL) | VAF 117/308 reads (38%) | called by mutect2, pindel, varscan2
- MRPL4 | c.915_921del p.A306Rfs*11 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- NPHP4 | c.1213G>C p.V405L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, varscan2
- PCBP2 | c.70_80del p.X24_splice | Splice Site (DEL) | VAF 39/147 reads (27%) | called by mutect2, pindel, varscan2
- PRR11 | c.185_201del p.W62* | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- SELENOP | c.780_796del p.N260Kfs*? | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- TENM1 | c.5932_5954delinsT p.L1978Sfs*6 | Frame Shift Del (DEL) | VAF 74/201 reads (37%) | called by pindel, varscan2*
- TPTE2 | c.279_300del p.D94Nfs*13 (on ENST00000400230 / NM_199254.2; = p.D57Nfs*13 on NM_130785.3) | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- TRANK1 | c.6308_6353del p.N2103Tfs*3 | Frame Shift Del (DEL) | VAF 31/144 reads (22%) | called by mutect2, pindel
- ADGRA2 | c.2607C>G p.P869= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV55104707; called by muse, mutect2, varscan2
- ALAS2 | c.1026G>A p.E342= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV58192245; called by muse, mutect2, varscan2
- ARAP2 | c.135G>A p.L45= | Silent (SNP) | VAF 150/305 reads (49%) | catalogued as COSV58289767; called by muse, mutect2, varscan2
- CACNG7 | c.732C>T p.S244= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as COSV55816050; called by muse, mutect2, varscan2
- DIP2C | c.1440C>G p.P480= | Silent (SNP) | VAF 256/813 reads (31%) | catalogued as COSV55169526; called by muse, mutect2, varscan2
- DOCK2 | c.2214G>A p.K738= | Silent (SNP) | VAF 16/367 reads (4%) | catalogued as COSV56959566; called by muse, mutect2
- EGFR | c.3579A>G p.E1193= | Silent (SNP) | VAF 21/189 reads (11%) | called by mutect2, varscan2
- EHHADH | c.1440G>C p.V480= | Silent (SNP) | VAF 44/301 reads (15%) | catalogued as COSV51631867; called by muse, mutect2, varscan2
- FBXO46 | c.1509C>T p.F503= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV58348558; called by muse, mutect2, varscan2
- FGFR4 | c.1341C>G p.A447= | Silent (SNP) | VAF 246/440 reads (56%) | catalogued as COSV52805573, COSV99451030; called by muse, mutect2, varscan2
- FRS3 | c.693A>C p.P231= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99443213; called by muse, varscan2
- KRTAP19-1 | c.183C>T p.G61= | Silent (SNP) | VAF 281/1211 reads (23%) | catalogued as COSV101185881; called by muse, mutect2, varscan2
- LILRB1 | c.351C>A p.G117= (on ENST00000427581; = p.G81= on NM_006669.6) | Silent (SNP) | VAF 78/408 reads (19%) | catalogued as rs755301934; called by muse, mutect2
- LRRC52 | c.30G>T p.G10= | Silent (SNP) | VAF 72/239 reads (30%) | catalogued as COSV54233017; called by muse, mutect2, varscan2
- MASP1 | c.720G>T p.V240= | Silent (SNP) | VAF 64/309 reads (21%) | catalogued as rs772872650, COSV51462151; called by muse, mutect2, varscan2
- MEGF8 | c.654G>A p.V218= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV52094208; called by muse, mutect2, varscan2
- P2RY1 | c.39G>A p.T13= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV59309997; called by muse, mutect2
- PGLYRP1 | c.590G>A p.*197= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV50517240; called by muse, mutect2, varscan2
- PNMA5 | c.423A>G p.Q141= | Silent (SNP) | VAF 147/264 reads (56%) | catalogued as COSV62625966; called by muse, mutect2, varscan2
- PTK2B | c.2310G>T p.R770= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV57761574; called by muse, mutect2, varscan2
- RIMS1 | c.5037A>G p.S1679= | Silent (SNP) | VAF 99/476 reads (21%) | catalogued as COSV99330844; called by muse, mutect2, varscan2
- SCN11A | c.2001A>T p.P667= | Silent (SNP) | VAF 132/309 reads (43%) | catalogued as COSV100182708; called by muse, mutect2, varscan2
- SLC9B1 | c.363T>C p.P121= | Silent (SNP) | VAF 69/257 reads (27%) | catalogued as COSV56468938, COSV56473183; called by muse, mutect2, varscan2
- SLCO2A1 | c.1785C>G p.A595= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV60487665; called by muse, mutect2, varscan2
- SLITRK5 | c.2775A>G p.V925= | Silent (SNP) | VAF 171/360 reads (48%) | catalogued as COSV61524694; called by muse, mutect2, varscan2
- TDRD10 | c.516G>T p.L172= | Silent (SNP) | VAF 20/746 reads (3%) | called by muse, mutect2
- TFEB | c.642G>C p.A214= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV57824856, COSV57825852; called by muse, mutect2, varscan2
- TLR5 | c.1404C>A p.T468= | Silent (SNP) | VAF 59/187 reads (32%) | catalogued as COSV60559947, COSV60560249; called by muse, mutect2, varscan2
- TPTE2 | c.465T>C p.D155= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV55025367; called by muse, mutect2, varscan2
- USHBP1 | c.1617G>A p.Q539= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1426157902, COSV53105094; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851073 T>A | 3'Flank (SNP) | VAF 89/266 reads (33%) | catalogued as rs773740184; called by muse, mutect2, varscan2
- RPL23AP42 | n.195T>A | RNA (SNP) | VAF 36/379 reads (9%) | called by muse, mutect2, varscan2
- RREB1 | c.3809-5942A>G | Intron (SNP) | VAF 61/187 reads (33%) | catalogued as COSV58561825; called by muse, mutect2, varscan2
- SUCO | chr1:172532594 G>C | 5'Flank (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99743950; called by muse, mutect2, varscan2
